Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13L, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13L-01A (Primary Tumor).

[page 1 of 3]
Reviewer Initials	R6 Date Reviewed: 11/15/10	

Clinical Diagnosis & History:

Thyroid nodule-FNA showed papillary thyroid cancer.

Specimens Submitted:

1: Thyroid, right thyroid lobe and isthmus; lobectomy

DIAGNOSIS:

1. Thyroid, right thyroid lobe and isthmus; lobectomy:

Tumor Type:

Papillary carcinoma, tall cell variant

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 1.4 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

No definite extrathyroidal extension is noted

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Microscopic foci present

One focus of papillary microcarcinoma is noted measuring < 0.1 cm

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

ICD-0-3

Carcinoma, papillary w tall cell variant

8344/3

hw

11/16/10

Site: thyroid, nos c73.9

[page 2 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Thyroid nodule-FNA showed papillary thyroid cancer.

Specimens Submitted:

1: Thyroid, right thyroid lobe and isthmus; lobectomy

DIAGNOSIS:

1. Thyroid, right thyroid lobe and isthmus; lobectomy:

Tumor Type:
Papillary carcinoma, tall cell variant

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Other Tumor Features:
Psammoma bodies

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 1.4 cm.

Tumor Encapsulation:
None Identified

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
No definite extrathyroidal extension is noted

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Microscopic foci present
One focus of papillary microcarcinoma is noted measuring < 0.1 cm

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:
Not identified

[page 3 of 3]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

1). The specimen is received fresh labeled "right thyroid lobe and isthmus, TPS, fresh and sterile". It consists of an unoriented, 13.5 g thyroid lobe measuring 5.5 x 3.5 x 1.5 cm with a 2.3 x 1 x 0.9 cm portion of isthmus and 3.3 x 1.5 cm, anteriorly attached portion of red-brown, striated muscle tissue. The surface shows a red-purple, intact capsule. The lobe is inked black posterior and blue anterior. Serial sectioning reveals a 1.4 x 0.9 x 0.8 cm ovoid, tan-white, firm nodule which abuts the capsule. The remainder of cut surface is red-tan and meaty. A portion of the specimen is submitted for TPS. Entirely submitted.

Summary of sections:

N - nodule
RL - right lobe
IS - isthmus

Summary of Sections:

Part 1: Thyroid, right thyroid lobe and isthmus; lobectomy

Block	Sect. Site	PCs
2	IS	4
2	N	2
10	RL	13

Source: NCI Genomic Data Commons file d1a7100c-e157-4ad9-ba7c-f518969f94b6 (TCGA-DJ-A13L.52AF2DB0-ABEF-44A8-ADD8-9A5E6F8EF624.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).